Somatic mutation profile of tumor specimen 0DSI8H from CCDI case PBCIED, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.1 years (3,694 days).
Specimen 0DSI8H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9f56b28-9de6-432c-9692-01aa8d203df5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI89 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa69bbdf-1985-4f2d-b829-21a3d523a8dd

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MOCS3 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 98/678 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs540199252, COSV99724468; called by muse, varscan2
- SYDE1 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as rs1031693933; called by muse, varscan2
- TGIF2LX | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 122/389 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs773693755, COSV99383199; called by muse, varscan2
- TLR4 | c.662G>T p.G221V (on ENST00000355622 / NM_138554.5; = p.G181V on NM_003266.4) | Missense Mutation (SNP) | VAF 90/687 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV62923034; called by muse, varscan2
- ARHGAP29 | c.2807C>T p.T936I | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, varscan2
- KIAA1549 | c.5074G>A p.D1692N | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZFP91 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); called by muse, varscan2
- LZTR1 | c.840C>G p.P280= | Silent (SNP) | VAF 29/288 reads (10%) | catalogued as rs1569155990; called by muse, varscan2
- SLC39A8 | c.447G>A p.L149= | Silent (SNP) | VAF 78/618 reads (13%) | called by muse, varscan2
